Somatic mutation profile of tumor specimen TARGET-10-PAREUH-09A (aliquot TARGET-10-PAREUH-09A-01D) from TARGET case TARGET-10-PAREUH, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 7.4 years (2,712 days).
Specimen TARGET-10-PAREUH-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 389fa5b0-1998-42f9-81e8-b738e1d2cc2f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PAREUH-10A (Blood Derived Normal), aliquot TARGET-10-PAREUH-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8b75b9a7-9813-4131-bf2c-2de3c2e4dd26

The open-access MAF lists 86 somatic variants for this specimen: 51 protein-altering or splice-affecting, 15 silent, 20 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 44, Silent 15, Intron 9, Nonsense Mutation 5, 3'UTR 4, 5'Flank 3, RNA 2, Nonstop Mutation 1, 3'Flank 1, Splice Region 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACAP3 | c.990C>G p.F330L | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.764); catalogued as COSV61223024; called by muse, mutect2, varscan2
- AKAP9 | c.4936G>A p.E1646K | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); catalogued as rs753713891; called by muse, mutect2, varscan2
- DOCK4 | c.2052G>T p.W684C | Missense Mutation (SNP) | VAF 38/109 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.912); catalogued as COSV101447860; called by muse, mutect2, varscan2
- DSCAM | c.5161G>A p.V1721I | Missense Mutation (SNP) | VAF 65/155 reads (42%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.93); catalogued as rs1315874600; called by muse, mutect2, varscan2
- EML6 | c.865G>A p.V289M | Missense Mutation (SNP) | VAF 9/98 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.736); catalogued as rs1324615744; called by muse, mutect2, varscan2
- GNB1L | c.379C>T p.R127C | Missense Mutation (SNP) | VAF 17/76 reads (22%) | SIFT tolerated (0.11); PolyPhen benign (0.001); catalogued as rs751815278, COSV61549194; called by muse, mutect2, varscan2
- HDAC1 | c.1195G>C p.D399H | Missense Mutation (SNP) | VAF 48/134 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.221); catalogued as rs369560330, COSV99051733; called by muse, mutect2, varscan2
- INVS | c.2279C>T p.S760F | Missense Mutation (SNP) | VAF 35/97 reads (36%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.123); catalogued as rs1324519096; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ITGA10 | c.2173C>T p.R725W | Missense Mutation (SNP) | VAF 40/114 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as rs782130276; called by muse, varscan2
- NNT | c.1604C>G p.S535* | Nonsense Mutation (SNP) | VAF 27/65 reads (42%) | catalogued as COSV52929886; called by muse, mutect2, varscan2
- NTNG1 | c.832G>A p.E278K | Missense Mutation (SNP) | VAF 20/89 reads (22%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.788); catalogued as rs780180788, COSV53979231; called by muse, mutect2, varscan2
- PBDC1 | c.271G>C p.E91Q | Missense Mutation (SNP) | VAF 20/115 reads (17%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.972); catalogued as COSV64895725; called by muse, mutect2, varscan2
- SCRIB | c.2032G>A p.E678K | Missense Mutation (SNP) | VAF 37/82 reads (45%) | SIFT tolerated (0.59); PolyPhen benign (0.209); catalogued as rs1554637241; called by muse, mutect2, varscan2
- SCRN3 | c.956C>T p.S319L | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT tolerated (0.21); PolyPhen benign (0.024); catalogued as COSV55809100; called by muse, mutect2, varscan2
- SEMA5A | c.1028C>T p.S343L | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.853); catalogued as rs200772051, COSV101227330; called by muse, mutect2, varscan2
- SETDB1 | c.3064G>A p.E1022K | Missense Mutation (SNP) | VAF 7/69 reads (10%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.266); catalogued as COSV54989826; called by muse, varscan2
- SI | c.4457C>T p.T1486M | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs557433017; called by muse, mutect2, varscan2
- TRAPPC3L | c.514C>T p.R172* | Nonsense Mutation (SNP) | VAF 30/108 reads (28%) | catalogued as rs749533621, COSV62068379; called by muse, mutect2, varscan2
- WFIKKN2 | c.1288G>A p.E430K | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT tolerated (0.12); PolyPhen benign (0.223); catalogued as COSV60958024; called by muse, mutect2, varscan2
- ZNF765 | c.1541G>C p.R514T | Missense Mutation (SNP) | VAF 61/178 reads (34%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.522); catalogued as COSV67182374; called by muse, mutect2, varscan2
- ZZZ3 | c.230G>A p.R77Q | Missense Mutation (SNP) | VAF 89/229 reads (39%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.048); catalogued as rs772221822, COSV66232753; called by muse, mutect2, varscan2
- ADAMTS2 | c.1721C>G p.S574* | Nonsense Mutation (SNP) | VAF 5/29 reads (17%) | called by muse, mutect2
- ANKRD31 | c.101G>C p.R34T | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.2); called by muse, mutect2, varscan2
- CHCHD2 | c.209C>T p.S70F | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- CHRDL2 | c.776A>G p.Y259C | Missense Mutation (SNP) | VAF 17/32 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DENND3 | c.12G>C p.L4F | Missense Mutation (SNP) | VAF 40/122 reads (33%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2
- DNAJC10 | c.2131G>C p.E711Q | Missense Mutation (SNP) | VAF 24/92 reads (26%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- GABRQ | c.448G>C p.D150H | Missense Mutation (SNP) | VAF 60/158 reads (38%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.923); called by muse, mutect2, varscan2
- GALNT7 | c.226G>A p.E76K | Missense Mutation (SNP) | VAF 13/70 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0.411); called by muse, mutect2, varscan2
- GDA | c.95A>G p.H32R | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT tolerated (0.54); PolyPhen benign (0.142); called by muse, mutect2, varscan2
- GK2 | c.1512G>C p.K504N | Missense Mutation (SNP) | VAF 65/158 reads (41%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- HAUS7 | c.157C>T p.L53F | Missense Mutation (SNP) | VAF 25/51 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- IER5L | c.1094C>T p.S365L | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.488); called by muse, mutect2, varscan2
- INO80 | c.1177G>A p.E393K | Missense Mutation (SNP) | VAF 46/125 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- IQGAP2 | c.1187G>T p.S396I | Missense Mutation (SNP) | VAF 20/196 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.15); called by muse, mutect2, varscan2
- LRMDA | c.560C>G p.S187* | Nonsense Mutation (SNP) | VAF 37/104 reads (36%) | called by muse, mutect2, varscan2
- MUC3A | c.7334C>G p.S2445C | Missense Mutation (SNP) | VAF 63/239 reads (26%) | SIFT deleterious, low confidence (0.02); called by muse, mutect2, varscan2
- NMT2 | c.76G>T p.G26W | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.958); called by muse, mutect2, varscan2
- PCDH7 | c.2651G>A p.R884K | Missense Mutation (SNP) | VAF 39/135 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.262); called by muse, mutect2, varscan2
- PCNT | c.2368G>C p.E790Q | Missense Mutation (SNP) | VAF 63/180 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, varscan2
- SCN7A | c.3823C>T p.Q1275* | Nonsense Mutation (SNP) | VAF 15/49 reads (31%) | called by muse, mutect2, varscan2
- SETDB1 | c.3876G>C p.*1292Yext*23 (on ENST00000271640 / NM_001366417.1; = p.*1291Yext*23 on NM_012432.4) | Nonstop Mutation (SNP) | VAF 7/51 reads (14%) | called by muse, mutect2, varscan2
- SP3 | c.2057G>C p.C686S | Missense Mutation (SNP) | VAF 36/89 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ST8SIA6 | c.358G>A p.E120K | Missense Mutation (SNP) | VAF 23/52 reads (44%) | SIFT deleterious (0.05); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- TAOK3 | c.2308G>C p.E770Q | Missense Mutation (SNP) | VAF 45/116 reads (39%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.917); called by muse, mutect2, varscan2
- TDRD6 | c.931G>C p.D311H | Missense Mutation (SNP) | VAF 32/113 reads (28%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- TMEM132D | c.2991C>G p.F997L | Missense Mutation (SNP) | VAF 23/80 reads (29%) | SIFT tolerated (0.66); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TOPBP1 | c.543G>C p.E181D | Missense Mutation (SNP) | VAF 32/74 reads (43%) | SIFT tolerated (0.6); PolyPhen benign (0); called by muse, mutect2, varscan2
- USP53 | c.574G>A p.E192K | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.932); called by muse, mutect2, varscan2
- YTHDC2 | c.*8-7C>G | Splice Region (SNP) | VAF 10/31 reads (32%) | called by muse, mutect2
- ZNF136 | c.1558C>G p.Q520E | Missense Mutation (SNP) | VAF 20/162 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.094); called by muse, mutect2, varscan2
- ACSM2B | c.258G>C p.L86= | Silent (SNP) | VAF 11/45 reads (24%) | called by muse, mutect2, varscan2
- CPXM2 | c.753C>T p.N251= | Silent (SNP) | VAF 37/83 reads (45%) | catalogued as rs751139397, COSV53865004; called by muse, mutect2
- ELN | c.2262G>A p.R754= (on ENST00000320399 / NM_001278939.1; = p.R721= on NM_000501.4) | Silent (SNP) | VAF 56/133 reads (42%) | catalogued as COSV52709346; called by muse, mutect2, varscan2
- ESRP2 | c.600C>T p.V200= | Silent (SNP) | VAF 47/121 reads (39%) | catalogued as COSV52176083; called by muse, mutect2, varscan2
- IPO5 | c.1080G>A p.K360= | Silent (SNP) | VAF 40/118 reads (34%) | catalogued as rs1453882527; called by muse, mutect2, varscan2
- MYH7 | c.2850C>G p.L950= | Silent (SNP) | VAF 41/109 reads (38%) | called by muse, mutect2, varscan2
- NTRK3 | c.840C>T p.F280= | Silent (SNP) | VAF 36/103 reads (35%) | called by muse, mutect2, varscan2
- PANK4 | c.1542G>A p.L514= | Silent (SNP) | VAF 22/44 reads (50%) | catalogued as rs770220379; called by muse, mutect2, varscan2
- PCLO | c.471C>T p.L157= | Silent (SNP) | VAF 49/127 reads (39%) | called by muse, mutect2, varscan2
- RSPO4 | c.675G>T p.V225= | Silent (SNP) | VAF 6/26 reads (23%) | called by muse, mutect2, varscan2
- SIX5 | c.1407C>T p.T469= | Silent (SNP) | VAF 4/40 reads (10%) | catalogued as rs982912854; called by muse, mutect2
- TEX47 | c.721C>T p.L241= | Silent (SNP) | VAF 16/75 reads (21%) | called by muse, mutect2, varscan2
- TPD52L1 | c.309G>C p.L103= | Silent (SNP) | VAF 27/99 reads (27%) | called by muse, mutect2, varscan2
- TTN | c.21717T>C p.R7239= (on ENST00000591111; = p.R6312= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 29/248 reads (12%) | called by muse, mutect2, varscan2
- VWA5B1 | c.2940C>T p.P980= (on ENST00000375079; = p.P975= on NM_001039500.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 7/60 reads (12%) | catalogued as rs1358580292; called by muse, mutect2, varscan2
- ACR | c.565+101C>T | Intron (SNP) | VAF 23/63 reads (37%) | catalogued as rs1334236964; called by muse, mutect2, varscan2
- ACR | c.565+731C>G | Intron (SNP) | VAF 42/125 reads (34%) | called by muse, mutect2, varscan2
- ACTRT1 | c.*80C>T | 3'UTR (SNP) | VAF 3/20 reads (15%) | called by muse, mutect2
- ANKRD13B | c.1652+22G>A | Intron (SNP) | VAF 9/35 reads (26%) | called by muse, mutect2, varscan2
- BAGE2 | chr21:10452506 A>G | 5'Flank (SNP) | VAF 4/22 reads (18%) | catalogued as rs75112368; called by mutect2, varscan2
- BIRC8 | n.1006C>G | RNA (SNP) | VAF 35/100 reads (35%) | catalogued as COSV101461279; called by muse, mutect2, varscan2
- CATSPERG | c.-15+416G>C | Intron (SNP) | VAF 9/49 reads (18%) | called by muse, mutect2, varscan2
- CHST11 | c.-76C>T | 5'UTR (SNP) | VAF 5/12 reads (42%) | called by mutect2, varscan2
- DST | c.4297-4596G>T | Intron (SNP) | VAF 33/93 reads (35%) | called by muse, mutect2, varscan2
- ERVV-1 | chr19:53009963 C>G | 5'Flank (SNP) | VAF 7/105 reads (7%) | called by muse, mutect2
- EVA1B | chr1:36327730 T>C | 5'Flank (SNP) | VAF 6/24 reads (25%) | called by muse, mutect2, varscan2
- FUNDC2P2 | n.594G>A | RNA (SNP) | VAF 9/85 reads (11%) | called by muse, mutect2, varscan2
- HOXB6 | c.*246C>T | 3'UTR (SNP) | VAF 5/67 reads (7%) | catalogued as rs1374164043; called by muse, mutect2
- MAP4K4 | chr2:101893041 A>C | 3'Flank (SNP) | VAF 77/259 reads (30%) | called by muse, mutect2, varscan2
- PANK4 | c.1219-78G>C | Intron (SNP) | VAF 23/46 reads (50%) | called by muse, mutect2, varscan2
- PCDH15 | c.*916G>C | 3'UTR (SNP) | VAF 9/24 reads (38%) | called by muse, mutect2, varscan2
- PIWIL1 | c.*70T>A | 3'UTR (SNP) | VAF 22/75 reads (29%) | called by muse, mutect2, varscan2
- PRR22 | c.194-25C>G | Intron (SNP) | VAF 22/79 reads (28%) | catalogued as COSV100288233, COSV100288570; called by muse, mutect2, varscan2
- RYR3 | c.3766-50C>G | Intron (SNP) | VAF 16/56 reads (29%) | called by muse, mutect2
- TAOK3 | c.2352+59G>C | Intron (SNP) | VAF 32/78 reads (41%) | called by muse, mutect2, varscan2
